FM case AD16767 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Germ Cell Neoplasms; Primary site: Heart, mediastinum, and pleura.
https://portal.gdc.cancer.gov/cases/c0f9af1d-eaff-4d55-a213-479d87837a34

Male, 36.7 years: Germ cell tumor, NOS (ICD-O-3 9064/3) of the mediastinum; metastasis biopsied or resected from the heart. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Metastatic.
